Somatic mutation profile of tumor specimen TCGA-AO-A128-01A (aliquot TCGA-AO-A128-01A-11D-A10M-09) from TCGA case TCGA-AO-A128, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 61.2 years (22,340 days).
Specimen TCGA-AO-A128-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed9b710f-c83f-4ab6-8cef-d0cc9f8aeeb4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A128-10A (Blood Derived Normal), aliquot TCGA-AO-A128-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66459662-4197-4286-a503-3f789c98a287

The open-access MAF lists 1,038 somatic variants for this specimen: 746 protein-altering or splice-affecting, 273 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 645, Silent 273, Frame Shift Del 40, Nonsense Mutation 24, Splice Site 20, Splice Region 8, 3'UTR 6, Intron 5, Frame Shift Ins 4, RNA 4, Nonstop Mutation 2, In Frame Del 2.

Variants (750 of 1,038; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGT | c.1290del p.F430Lfs*25 | Frame Shift Del (DEL) | VAF 44/212 reads (21%) | catalogued as rs387906578, CD065661; ClinVar: pathogenic; called by mutect2, varscan2
- FLNB | c.1592del p.G531Dfs*42 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HIVEP2 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 14/94 reads (15%) | catalogued as rs869312841, CM163425, COSV50014693; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC2A9 | c.1343C>T p.P448L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372201423, CM153726; ClinVar: likely pathogenic; called by mutect2, varscan2
- STAT3 | c.1229A>G p.H410R | Missense Mutation (SNP) | VAF 14/87 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV52885189; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA4 | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV64674791; called by muse, mutect2, varscan2
- ABCF3 | c.23T>C p.L8P | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV53048848; called by mutect2, varscan2
- ABHD16A | c.202T>C p.W68R | Missense Mutation (SNP) | VAF 38/172 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1305075160, COSV65452029; called by muse, varscan2
- ABHD16B | c.1117C>T p.R373C | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as COSV53863145; called by muse, mutect2, varscan2
- AC006059.2 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs558541969, COSV59607913; called by muse, mutect2, varscan2
- ACACA | c.6245A>G p.N2082S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1392881137; called by muse, mutect2, varscan2
- ACE | c.2768A>G p.E923G | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); catalogued as COSV52008997; called by muse, mutect2, varscan2
- ACIN1 | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 78/537 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52978098; called by muse, mutect2, varscan2
- ACOX2 | c.1783G>A p.A595T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.22); catalogued as rs1416209921, COSV57149671; called by muse, mutect2, varscan2
- ACSS1 | c.1361C>T p.A454V | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as COSV60221839; called by muse, mutect2, varscan2
- ACTL6A | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV66999131; called by muse, mutect2, varscan2
- ACTN2 | c.1525A>T p.K509* | Nonsense Mutation (SNP) | VAF 36/216 reads (17%) | catalogued as COSV63976246; called by muse, mutect2, varscan2
- ACTR8 | c.1798G>A p.E600K | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51637298; called by muse, mutect2, varscan2
- ADCY1 | c.1605+2T>C p.X535_splice | Splice Site (SNP) | VAF 9/109 reads (8%) | catalogued as COSV99811186; called by muse, mutect2
- ADGRL1 | c.2533A>G p.M845V (on ENST00000340736 / NM_001008701.3; = p.M840V on NM_014921.5) | Missense Mutation (SNP) | VAF 40/441 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.842); catalogued as COSV100529234; called by muse, mutect2
- ADIG | c.20C>A p.P7Q | Missense Mutation (SNP) | VAF 41/301 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV53439972; called by muse, mutect2, varscan2
- AFF1 | c.2945C>T p.T982M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs769048976, COSV57121334; called by muse, mutect2, varscan2
- AHNAK | c.8125A>G p.M2709V | Missense Mutation (SNP) | VAF 84/273 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.8); catalogued as COSV57218334; called by muse, mutect2, varscan2
- AIRE | c.1613G>A p.R538H | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs781319471, COSV52395061; called by muse, mutect2, varscan2
- AKAP12 | c.2130C>G p.D710E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV53577485; called by mutect2, varscan2
- AL121899.2 | c.1903C>T p.L635F | Missense Mutation (SNP) | VAF 62/240 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV67351190; called by muse, mutect2, varscan2
- AL162417.1 | c.298G>A p.A100T | Missense Mutation (SNP) | VAF 45/446 reads (10%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); catalogued as rs138007987; called by muse, mutect2, varscan2
- ALLC | c.598G>A p.A200T | Missense Mutation (SNP) | VAF 25/154 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as rs1183462682, COSV52993925, COSV52995824, COSV52997223; called by muse, mutect2, varscan2
- AMER1 | c.3004T>C p.S1002P | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV57662850; called by muse, mutect2, varscan2
- AMER2 | c.1741C>A p.L581M | Missense Mutation (SNP) | VAF 49/365 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV63438453; called by muse, mutect2, varscan2
- ANGEL2 | c.947G>T p.R316M | Missense Mutation (SNP) | VAF 9/112 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100853905; called by muse, mutect2
- ANGPT1 | c.797C>G p.T266S | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52445765, COSV99865072; called by muse, mutect2, varscan2
- ANGPTL1 | c.274C>T p.L92F | Missense Mutation (SNP) | VAF 22/386 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV99327922; called by muse, mutect2
- ANK1 | c.98G>A p.R33Q | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs747402381, COSV55880752; called by muse, mutect2, varscan2
- ANKRD26 | c.4876A>G p.I1626V | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.57); PolyPhen benign (0.058); catalogued as COSV65776428; called by muse, mutect2, varscan2
- ANKRD54 | c.589C>T p.R197* | Nonsense Mutation (SNP) | VAF 60/504 reads (12%) | catalogued as rs1334934252, COSV53235737; called by muse, mutect2, varscan2
- ANOS1 | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52922104; called by muse, mutect2, varscan2
- ANPEP | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 81/298 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as rs1055088958, COSV55592703, COSV55594073; called by muse, mutect2, varscan2
- AOPEP | c.886G>A p.A296T | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52919929; called by muse, mutect2, varscan2
- AOX1 | c.3062G>T p.R1021L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV65982520; called by muse, mutect2, varscan2
- AP3D1 | c.1279C>T p.R427W | Missense Mutation (SNP) | VAF 122/444 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs372956453; called by muse, mutect2, varscan2
- APC2 | c.1390C>A p.R464S | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52019803; called by muse, mutect2, varscan2
- APOB | c.9998C>T p.A3333V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51941454; called by muse, mutect2
- APOBR | c.1316A>G p.E439G (on ENST00000431282; = p.E448G on NM_018690.4) | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.074); catalogued as COSV60491684; called by muse, mutect2, varscan2
- ARAF | c.563G>A p.R188H | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.07); catalogued as rs777037087, COSV51691699; called by muse, mutect2, varscan2
- ARAP3 | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV53351848; called by muse, mutect2, varscan2
- ARFGEF3 | c.2404G>A p.A802T | Missense Mutation (SNP) | VAF 20/127 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV52461577; called by muse, mutect2, varscan2
- ARHGAP36 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763228565, COSV52264846; called by muse, mutect2, varscan2
- ARHGAP45 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as rs376691391; called by muse, mutect2, varscan2
- ARHGAP5 | c.3787C>T p.P1263S (on ENST00000345122 / NM_001030055.2; = p.P1262S on NM_001173.3) | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as rs759492227, COSV61537015; called by muse, mutect2, varscan2
- ARHGEF11 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs935349970, COSV63810717; called by muse, mutect2
- ARHGEF2 | c.2665G>A p.A889T (on ENST00000361247 / NM_001162383.2; = p.A861T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.413); catalogued as rs760566971, COSV58112787; called by muse, mutect2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 8/49 reads (16%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARHGEF7 | c.1321T>C p.F441L (on ENST00000375741 / NM_001113511.2; = p.F263L on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54545880; called by muse, mutect2, varscan2
- ARL15 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1273284517, COSV72291131; called by muse, mutect2, varscan2
- ARMC7 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.021); catalogued as COSV55461155; called by muse, mutect2, varscan2
- ARMC9 | c.880-1G>A p.X294_splice | Splice Site (SNP) | VAF 88/592 reads (15%) | catalogued as COSV63022017; called by muse, mutect2, varscan2
- ASB17 | c.530del p.N177Tfs*7 | Frame Shift Del (DEL) | VAF 26/90 reads (29%) | catalogued as rs749460467; called by mutect2, pindel, varscan2
- ASPG | c.1145C>A p.S382Y | Missense Mutation (SNP) | VAF 24/139 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV71933920; called by muse, mutect2, varscan2
- ASPSCR1 | c.1094G>A p.R365H | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs996593288, COSV60728638; called by muse, mutect2, varscan2
- ATAD3A | c.1820A>G p.Q607R | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59234285; called by muse, mutect2, varscan2
- ATG2B | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs375023828; called by muse, mutect2, varscan2
- ATG9A | c.851A>G p.Q284R | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.046); catalogued as rs1226395938, COSV100772452; called by muse, mutect2
- ATP10A | c.1871G>A p.S624N | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs1331815448, COSV63519529; called by muse, mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP1B4 | c.912+1G>A p.X304_splice (on ENST00000218008 / NM_001142447.3; = p.X300_splice on NM_012069.5) | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as rs777822720, COSV54313550; called by muse, mutect2, varscan2
- ATP2C1 | c.257T>C p.L86P | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60758374; called by muse, mutect2
- ATR | c.6196C>T p.R2066W | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as rs369309229; called by muse, mutect2
- ATRAID | c.371A>G p.K124R (on ENST00000611786; = p.K11R on NM_016085.5) | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV53028617; called by muse, mutect2, varscan2
- ATXN1 | c.1897G>A p.V633I | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as rs201516255, COSV55208992; called by muse, mutect2, varscan2
- ATXN2 | c.3743A>G p.Q1248R (on ENST00000550104; = p.Q1088R on NM_002973.4) | Missense Mutation (SNP) | VAF 59/473 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.165); catalogued as rs1208628975, COSV57984387; called by muse, mutect2, varscan2
- ATXN3 | c.674A>C p.D225A | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV61496139; called by muse, mutect2, varscan2
- AUNIP | c.748T>C p.Y250H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV65353056; called by muse, mutect2, varscan2
- AVPR1B | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV100899298; called by muse, mutect2
- B4GALNT4 | c.2678G>A p.R893H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57324170; called by muse, mutect2, varscan2
- BAIAP3 | c.3403G>A p.G1135R | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs754394948, COSV50104328, COSV50105887; called by muse, mutect2, varscan2
- BBOX1 | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as rs934940380, COSV54192034, COSV54193018; called by muse, mutect2, varscan2
- BCAR1 | c.860A>G p.Y287C | Missense Mutation (SNP) | VAF 50/290 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1437454366, COSV50788470; called by muse, mutect2, varscan2
- BDH1 | c.14G>A p.R5H | Missense Mutation (SNP) | VAF 29/251 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs115296714; called by muse, mutect2, varscan2
- BET1 | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.286); catalogued as COSV55993112; called by muse, mutect2, varscan2
- BMF | c.43T>C p.F15L | Missense Mutation (SNP) | VAF 57/241 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV55019311; called by muse, mutect2, varscan2
- BMP2 | c.231del p.Y78Tfs*3 | Frame Shift Del (DEL) | VAF 7/65 reads (11%) | catalogued as COSV66577890; called by mutect2, pindel
- BNIP3 | c.377G>A p.S126N | Missense Mutation (SNP) | VAF 36/205 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.331); catalogued as COSV64044079; called by muse, mutect2, varscan2
- BPIFB3 | c.347A>G p.Q116R | Missense Mutation (SNP) | VAF 21/140 reads (15%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.982); catalogued as COSV64957554; called by muse, mutect2, varscan2
- BRD1 | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV53459016; called by muse, mutect2, varscan2
- BRS3 | c.1111G>A p.V371I | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV101036413; called by muse, mutect2, varscan2
- BUB3 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs753417733, COSV64363817; called by muse, mutect2, varscan2
- C19orf44 | c.1149+2T>C p.X383_splice | Splice Site (SNP) | VAF 11/68 reads (16%) | catalogued as COSV55612871; called by muse, mutect2, varscan2
- C2CD2L | c.2008G>A p.A670T | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV60884291; called by muse, mutect2, varscan2
- C2CD6 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 20/142 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV53795745, COSV53796834; called by muse, mutect2, varscan2
- C2orf16 | c.2386C>A p.L796I | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs746171023, COSV62676693; called by muse, mutect2, varscan2
- C9orf50 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 58/140 reads (41%) | catalogued as COSV65252636; called by muse, mutect2, varscan2
- CA5B | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59416887; called by muse, mutect2, varscan2
- CABP7 | c.478A>C p.S160R | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.303); catalogued as COSV99334668; called by muse, mutect2
- CACTIN | c.1021A>G p.M341V | Missense Mutation (SNP) | VAF 47/347 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as rs1313709774, COSV50269391; called by muse, mutect2, varscan2
- CADM3 | c.715C>T p.P239S (on ENST00000368125 / NM_001127173.3; = p.P273S on NM_021189.5) | Missense Mutation (SNP) | VAF 36/354 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.088); catalogued as COSV63686120; called by muse, mutect2
- CALCRL | c.236C>T p.A79V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.101); catalogued as rs1342504956, COSV66475800; called by muse, mutect2, varscan2
- CAMK1G | c.289A>G p.M97V | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV50523213; called by muse, mutect2, varscan2
- CAMKK1 | c.583C>T p.R195W | Missense Mutation (SNP) | VAF 23/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751713715, COSV50119983; called by muse, mutect2, varscan2
- CANT1 | c.941G>A p.R314H | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as rs1293634752, COSV100185146; called by muse, mutect2
- CAPN15 | c.1588A>G p.R530G | Missense Mutation (SNP) | VAF 26/137 reads (19%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV54837265; called by muse, mutect2, varscan2
- CASK | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as rs1012863843, COSV59369981; called by muse, mutect2, varscan2
- CASS4 | c.1769G>A p.R590Q | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775960291, COSV64387258; called by muse, mutect2, varscan2
- CAVIN1 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 67/543 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1567776298, COSV63812204; called by muse, mutect2, varscan2
- CBARP | c.764C>T p.A255V (on ENST00000382477; = p.A235V on NM_152769.3) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1421499683, COSV53067678; called by muse, mutect2
- CBFB | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV51999364; called by muse, mutect2, varscan2
- CBLL1 | c.403A>G p.I135V | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0.015); catalogued as rs763554958, COSV56029598; called by muse, mutect2, varscan2
- CBX4 | c.530A>G p.H177R | Missense Mutation (SNP) | VAF 47/300 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.079); catalogued as COSV53966152; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 21/137 reads (15%) | catalogued as rs780649799; called by mutect2, varscan2
- CCAR1 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56266960; called by muse, mutect2, varscan2
- CCDC137 | c.784T>C p.Y262H | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61303489; called by muse, mutect2, varscan2
- CCDC180 | c.4706G>T p.R1569M | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV63831807; called by muse, mutect2, varscan2
- CCDC40 | c.2276T>C p.L759P | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV66476119; called by muse, mutect2, varscan2
- CCDC73 | c.657del p.A220Qfs*5 | Frame Shift Del (DEL) | VAF 8/53 reads (15%) | catalogued as rs749079180; called by mutect2, pindel, varscan2
- CCDC80 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.132); catalogued as rs371496097; called by muse, mutect2, varscan2
- CCN1 | c.685T>C p.C229R | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV71704378; called by muse, mutect2, varscan2
- CCN2 | c.526G>T p.G176W | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100915275; called by muse, mutect2
- CDC27 | c.790del p.T264Lfs*6 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | catalogued as COSV50378440; called by mutect2, pindel, varscan2
- CDC42EP1 | c.388T>C p.Y130H | Missense Mutation (SNP) | VAF 30/255 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.903); catalogued as COSV50757140; called by muse, mutect2, varscan2
- CDH1 | c.2450C>T p.A817V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs587782024, COSV55732374; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDON | c.1621A>C p.S541R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV54999531; called by muse, mutect2
- CEBPE | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 28/178 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs779209834, COSV52830155; called by muse, mutect2, varscan2
- CEL | c.1709A>G p.E570G (on ENST00000673714; = p.E567G on NM_001807.6) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs755884951, COSV100672204; called by muse, mutect2
- CEP250 | c.416A>G p.E139G | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV61171369; called by muse, mutect2, varscan2
- CEP290 | c.1805T>C p.M602T | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs1321355912, COSV58353231; called by muse, mutect2, varscan2
- CFAP74 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.517); catalogued as COSV54569759; called by muse, mutect2, varscan2
- CFHR1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 34/339 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV57627802; called by muse, mutect2
- CHCHD10 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as rs562212051, COSV59418287; called by muse, mutect2
- CHCHD6 | c.88-2A>G p.X30_splice | Splice Site (SNP) | VAF 16/133 reads (12%) | catalogued as COSV99335596; called by muse, mutect2, varscan2
- CHD2 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs776934265, COSV59121024; called by mutect2, varscan2
- CHRNB2 | c.384G>T p.E128D | Missense Mutation (SNP) | VAF 37/264 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as COSV100872680, COSV63808598; called by muse, varscan2
- CIAPIN1 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs745916329, COSV67953366; called by muse, mutect2, varscan2
- CLCN6 | c.1232A>G p.D411G | Missense Mutation (SNP) | VAF 58/388 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56741236; called by muse, mutect2, varscan2
- CLIP2 | c.1925A>G p.Q642R | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV56281272; called by muse, mutect2, varscan2
- CLSTN3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.053); catalogued as rs749951518, COSV56937897, COSV99866361; called by muse, mutect2, varscan2
- CNBD2 | c.243G>T p.E81D | Missense Mutation (SNP) | VAF 34/206 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV62587283; called by muse, mutect2, varscan2
- CNOT6 | c.1229G>A p.C410Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745926565, COSV99993377; called by mutect2, varscan2
- CNTN5 | c.815A>G p.K272R | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.936); catalogued as COSV54325457; called by muse, mutect2, varscan2
- COL14A1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs771290485, COSV52850061; called by muse, mutect2, varscan2
- COL5A1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV65669700; called by muse, mutect2, varscan2
- COL5A1 | c.958A>G p.M320V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1318518071, COSV100879424; called by muse, mutect2
- COL6A1 | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146622557; ClinVar: uncertain significance; called by muse, varscan2
- COL6A3 | c.7151A>G p.K2384R | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.305); catalogued as COSV55095636, COSV99797510; called by muse, mutect2, varscan2
- COL7A1 | c.8544G>T p.E2848D | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.038); catalogued as COSV56476735; called by muse, mutect2, varscan2
- COL7A1 | c.6573+2T>C p.X2191_splice | Splice Site (SNP) | VAF 17/141 reads (12%) | catalogued as COSV100094906; called by muse, mutect2, varscan2
- COQ10B | c.486G>T p.E162D | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.241); catalogued as COSV55836883; called by muse, mutect2, varscan2
- COX5B | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.319); catalogued as rs746587601, COSV51480921; called by muse, mutect2, varscan2
- CP | c.1468T>C p.Y490H | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV52831684; called by muse, mutect2, varscan2
- CPQ | c.1327A>G p.M443V | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV55151147; called by muse, mutect2, varscan2
- CRAT | c.221A>G p.Q74R | Missense Mutation (SNP) | VAF 67/261 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100533924; called by muse, mutect2, varscan2
- CREBBP | c.6803T>C p.M2268T | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.599); catalogued as COSV52129322; called by muse, mutect2, varscan2
- CRNKL1 | c.2113C>T p.R705W | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV58548613; called by mutect2, varscan2
- CRTAC1 | c.491A>G p.E164G | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.272); catalogued as COSV54004269; called by muse, mutect2, varscan2
- CRYBA1 | c.8C>T p.T3I | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV99836931; called by muse, mutect2
- CRYGD | c.455G>T p.R152M | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1215844475, COSV100005964; called by muse, mutect2, varscan2
- CSF1 | c.211G>C p.D71H | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60034028; called by muse, mutect2, varscan2
- CSH1 | c.409T>C p.Y137H | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV60242528; called by muse, mutect2, varscan2
- CSMD3 | c.3707G>T p.R1236M (on ENST00000297405 / NM_001363185.1; = p.R1132M on NM_052900.3) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52225719, COSV52227624, COSV52294338; called by muse, mutect2, varscan2
- CTSA | c.688A>G p.N230D | Missense Mutation (SNP) | VAF 46/420 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV51943053; called by muse, varscan2
- CTSD | c.1105G>A p.G369S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52588568; called by muse, mutect2, varscan2
- CTSL | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 51/383 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.931); catalogued as COSV58245695, COSV58245877; called by muse, mutect2, varscan2
- CTSV | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 51/311 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.882); catalogued as rs1331444584, COSV52345171; called by muse, mutect2, varscan2
- CTU2 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370063135; called by mutect2, varscan2
- CUL9 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52730567; called by muse, mutect2, varscan2
- CXCL2 | c.16C>T p.L6F | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.346); catalogued as COSV56021800; called by muse, mutect2, varscan2
- CYB5A | c.232A>C p.T78P | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.23); catalogued as COSV55022344; called by muse, mutect2
- CYP4F12 | c.491T>C p.I164T | Missense Mutation (SNP) | VAF 16/147 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV61174771; called by muse, mutect2, varscan2
- CYP7A1 | c.818T>C p.L273P | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs778199686, COSV56964337; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAGLA | c.442A>G p.S148G | Missense Mutation (SNP) | VAF 31/225 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV57197483; called by muse, mutect2, varscan2
- DCAF11 | c.655T>C p.W219R | Missense Mutation (SNP) | VAF 38/232 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58109666; called by muse, mutect2
- DCLK2 | c.895T>C p.S299P | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56206692; called by muse, mutect2, varscan2
- DCP1B | c.1371G>C p.Q457H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV54970355; called by muse, mutect2, varscan2
- DDX39A | c.1267A>C p.I423L | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV54392231; called by muse, mutect2, varscan2
- DDX55 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 43/170 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV53016615; called by muse, mutect2, varscan2
- DECR1 | c.171T>G p.F57L | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as COSV55169282; called by muse, mutect2
- DEFB121 | c.50T>C p.V17A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.024); catalogued as COSV66236466; called by muse, mutect2, varscan2
- DENND4B | c.1802A>G p.N601S | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV63410205; called by muse, mutect2
- DEPDC5 | c.3446G>A p.R1149Q (on ENST00000400246; = p.R1218Q on NM_014662.5) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.993); catalogued as rs747454808, COSV56702043; called by muse, mutect2, varscan2
- DHX34 | c.2755C>T p.R919C | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs772022162, COSV60896076; called by muse, mutect2, varscan2
- DHX38 | c.133C>T p.R45C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs372776663, COSV99194278; called by mutect2, varscan2
- DIDO1 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as rs1345025577, COSV56626700; called by muse, mutect2, varscan2
- DIP2C | c.1204G>A p.G402S | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55164906; called by muse, mutect2, varscan2
- DLL3 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 178/543 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs538488581, COSV52695310; called by muse, mutect2, varscan2
- DMGDH | c.362A>G p.E121G | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV54865568; called by muse, mutect2, varscan2
- DNAH1 | c.307A>G p.S103G | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1241459648, COSV101324559; called by muse, mutect2
- DNAH1 | c.6500A>G p.E2167G | Missense Mutation (SNP) | VAF 34/302 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.139); catalogued as COSV70231206; called by muse, mutect2, varscan2
- DNAH17 | c.6580A>G p.T2194A | Missense Mutation (SNP) | VAF 82/565 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.031); catalogued as COSV67757375; called by muse, mutect2, varscan2
- DNAH2 | c.12067C>A p.L4023I | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.074); catalogued as COSV66721682; called by muse, mutect2, varscan2
- DNAJB2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.058); catalogued as rs200970147, COSV55349520; called by muse, mutect2, varscan2
- DNAJB6 | c.626T>C p.V209A | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV51096964; called by muse, mutect2, varscan2
- DNAJC14 | c.1123C>T p.Q375* | Nonsense Mutation (SNP) | VAF 11/111 reads (10%) | catalogued as COSV57913435; called by muse, mutect2, varscan2
- DNAJC30 | c.206A>G p.Y69C | Missense Mutation (SNP) | VAF 24/256 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56096561, COSV99736253; called by muse, mutect2
- DNM1 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 10/112 reads (9%) | catalogued as COSV100359413; called by muse, mutect2
- DNMT3A | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.593); catalogued as rs1483397095, COSV53061689, COSV53083425; called by muse, mutect2, varscan2
- DOT1L | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 148/740 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67110928; called by muse, varscan2
- DRC3 | c.999G>A p.S333= | Splice Region (SNP) | VAF 32/77 reads (42%) | catalogued as rs1459977522, COSV58261707; called by muse, mutect2, varscan2
- DSCAML1 | c.2686C>T p.R896W (on ENST00000321322; = p.R836W on NM_020693.4) | Missense Mutation (SNP) | VAF 68/410 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771889195, COSV58395371; called by muse, mutect2, varscan2
- DSG3 | c.2339C>T p.A780V | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.363); catalogued as rs1405626377, COSV57127498; called by muse, mutect2, varscan2
- DSN1 | c.188G>A p.G63E | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1259833504, COSV65519555; called by muse, mutect2, varscan2
- DUSP2 | c.625T>C p.C209R | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56620252; called by muse, mutect2, varscan2
- DYNC1H1 | c.12191C>T p.T4064M | Missense Mutation (SNP) | VAF 102/346 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs750249796, COSV64135613; called by muse, mutect2, varscan2
- DYNC1LI1 | c.1288del p.I430Lfs*5 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs748891796; called by mutect2, varscan2
- DYRK3 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782184680, COSV65606720; called by muse, mutect2, varscan2
- DYRK3 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782784518, COSV100895587; called by mutect2, varscan2
- DYSF | c.2380G>A p.V794I | Missense Mutation (SNP) | VAF 63/205 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs371609233; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DZANK1 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as COSV99361605; called by muse, mutect2
- EGFL7 | c.549dup p.R184Qfs*100 | Frame Shift Ins (INS) | VAF 12/34 reads (35%) | catalogued as rs878890965; called by mutect2, varscan2
- EGFR | c.2700C>T p.Y900= | Splice Region (SNP) | VAF 12/135 reads (9%) | catalogued as rs530256683, COSV99286463; ClinVar: uncertain significance; called by muse, mutect2
- EIF5B | c.2641C>T p.R881C | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.15); catalogued as rs1313208013, COSV56812170; called by muse, mutect2
- ELAC2 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as COSV100568330; called by muse, mutect2
- ELAVL3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as rs778296387, COSV63645455; called by muse, mutect2, varscan2
- EPHB3 | c.2983C>T p.P995S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as COSV57807130; called by muse, mutect2, varscan2
- EPS15L1 | c.1132G>A p.G378R | Missense Mutation (SNP) | VAF 31/212 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs143490617; called by muse, mutect2, varscan2
- ERBB2 | c.2390T>C p.V797A | Missense Mutation (SNP) | VAF 35/269 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54074440; called by muse, mutect2, varscan2
- ERCC6L | c.3142A>G p.T1048A | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as COSV57821259; called by muse, mutect2, varscan2
- ESPN | c.1129C>A p.L377I | Missense Mutation (SNP) | VAF 70/544 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.275); catalogued as COSV64704698; called by muse, mutect2, varscan2
- ESS2 | c.1346G>A p.R449H | Missense Mutation (SNP) | VAF 58/331 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs142803658; called by muse, mutect2, varscan2
- ESS2 | c.1168C>A p.L390M | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV52817446; called by muse, mutect2, varscan2
- ETV3L | c.6C>A p.H2Q | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV101485558, COSV71901200; called by muse, mutect2
- EXD3 | c.1927C>T p.R643W | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764339032, COSV59808957; called by muse, mutect2, varscan2
- EXO1 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as COSV62218213; called by muse, mutect2
- F10 | c.1120T>C p.S374P | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as rs121964941, CM940382, COSV65022242; called by muse, mutect2, varscan2
- FAAH | c.1740A>G p.*580Wext*8 | Nonstop Mutation (SNP) | VAF 33/209 reads (16%) | catalogued as COSV54544710; called by muse, mutect2, varscan2
- FAM102A | c.775C>A p.R259S (on ENST00000373095 / NM_001035254.3; = p.R117S on NM_203305.2) | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100305376; called by muse, mutect2
- FAM160A2 | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV56412390; called by muse, mutect2, varscan2
- FAM166B | c.334G>A p.V112I | Missense Mutation (SNP) | VAF 34/198 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as COSV63429171; called by muse, mutect2, varscan2
- FAM71E1 | c.449G>T p.G150V (on ENST00000600100 / NM_001308429.2; = p.G134V on NM_138411.3) | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100618395; called by muse, mutect2
- FAXDC2 | c.884A>G p.H295R | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100303369; called by mutect2, varscan2
- FBLIM1 | c.145A>G p.M49V | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1321625525, COSV60030385; called by muse, mutect2
- FCGR1A | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 45/421 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.056); catalogued as COSV64985689; called by muse, mutect2, varscan2
- FCGR3B | c.61+1G>A p.X21_splice | Splice Site (SNP) | VAF 14/89 reads (16%) | catalogued as COSV54210615; called by muse, mutect2, varscan2
- FCGRT | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.68); PolyPhen probably damaging (0.968); catalogued as rs1163474595, COSV54542654; called by muse, mutect2, varscan2
- FER1L6 | c.76+2T>C p.X26_splice | Splice Site (SNP) | VAF 10/78 reads (13%) | catalogued as COSV67551006; called by muse, mutect2, varscan2
- FGD6 | c.3530C>T p.A1177V | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377183623; called by muse, mutect2, varscan2
- FGF8 | c.550C>T p.R184W (on ENST00000344255 / NM_033164.4; = p.R166W on NM_006119.6) | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs548987968, COSV60142143; called by muse, mutect2, varscan2
- FGR | c.781A>G p.S261G | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64969601; called by muse, mutect2, varscan2
- FHOD3 | c.2618A>G p.Q873R (on ENST00000359247 / NM_001281739.3; = p.Q890R on NM_025135.5) | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs747642309, COSV57178150; called by muse, mutect2, varscan2
- FITM1 | c.288G>T p.W96C | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV52824673; called by muse, mutect2, varscan2
- FLNA | c.5164A>G p.I1722V (on ENST00000369850 / NM_001110556.2; = p.I1714V on NM_001456.3) | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.326); catalogued as COSV61046271; called by muse, mutect2, varscan2
- FLNA | c.4757A>G p.D1586G | Missense Mutation (SNP) | VAF 79/637 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.282); catalogued as COSV61046289; called by muse, mutect2, varscan2
- FLT1 | c.3929A>G p.D1310G | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV56732533; called by muse, mutect2, varscan2
- FLT3LG | c.351del p.S118Afs*24 | Frame Shift Del (DEL) | VAF 32/128 reads (25%) | catalogued as rs769482947; called by mutect2, varscan2
- FOXG1 | c.98A>G p.H33R | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.015); catalogued as rs1478379479, COSV100486522; called by muse, mutect2
- FRAS1 | c.2774G>T p.C925F | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53623189; called by muse, mutect2
- FTSJ1 | c.23A>C p.K8T | Missense Mutation (SNP) | VAF 17/262 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99191373; called by muse, mutect2
- FURIN | c.356C>A p.P119H | Missense Mutation (SNP) | VAF 127/451 reads (28%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.572); catalogued as COSV51576565; called by muse, mutect2, varscan2
- FUT2 | c.125C>T p.P42L | Missense Mutation (SNP) | VAF 20/317 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.053); catalogued as rs756430917; called by muse, mutect2
- FYB1 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100684741; called by muse, mutect2
- GALNT17 | c.250T>C p.S84P | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61169777; called by muse, mutect2, varscan2
- GALNTL5 | c.922T>G p.S308A | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67180483; called by muse, varscan2
- GBA2 | c.1816G>A p.V606I | Missense Mutation (SNP) | VAF 36/339 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs754032114, COSV62306306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GBF1 | c.3289C>T p.P1097S (on ENST00000369983 / NM_001377137.1; = p.P1096S on NM_004193.3) | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100890291; called by muse, mutect2, varscan2
- GIMAP1 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.904); catalogued as COSV56187144; called by muse, mutect2, varscan2
- GIT1 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.104); catalogued as rs758906145, COSV56403022; called by muse, mutect2, varscan2
- GMFG | c.4-1G>A p.X2_splice | Splice Site (SNP) | VAF 12/110 reads (11%) | catalogued as rs1219864498, COSV53419419; called by muse, mutect2, varscan2
- GNA11 | c.388A>G p.S130G | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV50025038, COSV99312652; called by muse, mutect2
- GNB5 | c.344A>G p.K115R (on ENST00000261837 / NM_016194.4; = p.K73R on NM_006578.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV55899974; called by muse, mutect2, varscan2
- GNPTAB | c.3380G>A p.R1127H | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.167); catalogued as rs749361169, COSV54779514; called by muse, mutect2, varscan2
- GON4L | c.816G>A p.M272I | Missense Mutation (SNP) | VAF 58/580 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV55196717; called by muse, mutect2
- GPAT3 | c.31C>A p.L11I | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs780179869, COSV52357977; called by muse, mutect2, varscan2
- GPC2 | c.439C>T p.R147W | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1229970899, COSV52785576; called by muse, mutect2, varscan2
- GPR158 | c.2254C>T p.R752C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1350723305, COSV66274209; called by muse, mutect2, varscan2
- GRIN2C | c.1073T>C p.M358T | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV53114866; called by muse, mutect2
- GRIN2D | c.1363T>C p.C455R | Missense Mutation (SNP) | VAF 21/195 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54380252; called by muse, mutect2, varscan2
- GRK2 | c.517C>T p.R173W | Missense Mutation (SNP) | VAF 41/275 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57950477; called by muse, mutect2, varscan2
- H2AC14 | c.170A>G p.E57G | Missense Mutation (SNP) | VAF 13/163 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV60798153; called by muse, mutect2, varscan2
- H2BW1 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.014); catalogued as rs138073152, COSV54220856; called by muse, mutect2, varscan2
- HAND2 | c.504G>T p.K168N | Missense Mutation (SNP) | VAF 40/740 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.694); catalogued as rs776061276, COSV100854134, COSV64019110; called by muse, mutect2
- HBS1L | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370235823, COSV63200128; called by muse, mutect2, varscan2
- HEG1 | c.2305A>G p.M769V | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV60763410; called by muse, mutect2, varscan2
- HELQ | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as COSV55025960; called by muse, mutect2, varscan2
- HELZ2 | c.1903C>T p.R635W (on ENST00000467148 / NM_001037335.2; = p.R66W on NM_033405.3) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs369045635; called by muse, mutect2, varscan2
- HIPK2 | c.2665A>G p.T889A | Missense Mutation (SNP) | VAF 72/518 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61229537; called by muse, mutect2, varscan2
- HK3 | c.2489A>C p.Q830P | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.88); catalogued as COSV52841788; called by muse, mutect2, varscan2
- HMCN1 | c.6141A>C p.K2047N | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99623594; called by muse, mutect2
- HNRNPUL2 | c.1669C>T p.R557W | Missense Mutation (SNP) | VAF 69/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57132743; called by muse, mutect2, varscan2
- HOMEZ | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs774260897, COSV62537403; called by muse, mutect2, varscan2
- HOOK2 | c.1283C>T p.P428L | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.691); catalogued as rs750079184, COSV53402836; called by muse, mutect2, varscan2
- HPS1 | c.403C>T p.R135W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759982308, COSV57268678; called by muse, mutect2
- HSPG2 | c.11908G>A p.G3970R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs762861100, COSV100760687, COSV60828803; called by muse, mutect2, varscan2
- HTR2A | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66327667; called by muse, mutect2, varscan2
- IFNAR2 | c.1432C>T p.Q478* | Nonsense Mutation (SNP) | VAF 23/112 reads (21%) | catalogued as rs1360373883, COSV51616370; called by muse, mutect2, varscan2
- IGF2BP2 | c.409A>G p.M137V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV60487599; called by muse, varscan2
- IGF2R | c.4067G>A p.R1356Q | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.51); catalogued as rs756307482, COSV63630005; called by muse, mutect2, varscan2
- IGFN1 | c.1987C>A p.L663I (on ENST00000295591 / NM_001367841.1; = p.L3120I on NM_001164586.2) | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.401); catalogued as COSV55176197; called by muse, mutect2, varscan2
- IGHMBP2 | c.608C>T p.A203V | Missense Mutation (SNP) | VAF 34/240 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs373012350; called by muse, mutect2, varscan2
- IGSF3 | c.2396C>T p.A799V (on ENST00000369486 / NM_001007237.3; = p.A819V on NM_001542.4) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV59593621; called by muse, mutect2, varscan2
- IGSF8 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 26/302 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.692); catalogued as rs145403328, COSV100081599; called by muse, mutect2
- IL23R | c.1238A>T p.Q413L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV61374991; called by muse, mutect2, varscan2
- INCENP | c.1391A>G p.Q464R | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV53917313; called by muse, mutect2, varscan2
- INPP5B | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV65958400; called by muse, mutect2, varscan2
- IP6K1 | c.1244A>G p.H415R | Missense Mutation (SNP) | VAF 26/184 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1352085173, COSV57695844; called by muse, mutect2, varscan2
- IQCE | c.670C>T p.Q224* | Nonsense Mutation (SNP) | VAF 21/216 reads (10%) | catalogued as COSV100383151; called by muse, mutect2, varscan2
- ITGA9 | c.1663T>C p.C555R | Missense Mutation (SNP) | VAF 21/151 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53246275; called by muse, mutect2, varscan2
- ITGAL | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 58/495 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV63322941; called by muse, mutect2, varscan2
- ITGB8 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 19/250 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99750462; called by muse, mutect2
- ITIH3 | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 30/244 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.069); catalogued as rs765314854, COSV69649389; called by muse, mutect2, varscan2
- ITPR3 | c.5800G>A p.V1934M | Missense Mutation (SNP) | VAF 19/142 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs778613128, COSV65410890; called by muse, mutect2, varscan2
- JAKMIP1 | c.967C>T p.R323* | Nonsense Mutation (SNP) | VAF 36/123 reads (29%) | catalogued as rs1344392658, COSV51535850; called by muse, mutect2, varscan2
- JAKMIP3 | c.1924T>C p.Y642H | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as COSV53825186; called by muse, mutect2, varscan2
- JCAD | c.2028G>T p.K676N | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); catalogued as COSV100948035; called by muse, mutect2
- KBTBD6 | c.1891A>G p.T631A | Missense Mutation (SNP) | VAF 33/287 reads (11%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as COSV65271560; called by muse, mutect2, varscan2
- KCNA4 | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0); catalogued as COSV60253675; called by muse, mutect2, varscan2
- KCNE1 | c.212T>C p.L71P | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV100492387; called by mutect2, varscan2
- KCNF1 | c.424G>A p.A142T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.875); catalogued as COSV54464237; called by muse, mutect2, varscan2
- KCNU1 | c.1731A>C p.Q577H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as COSV67757447; called by muse, mutect2, varscan2
- KCNV2 | c.140C>T p.T47I | Missense Mutation (SNP) | VAF 63/286 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs367879192; called by muse, mutect2, varscan2
- KHSRP | c.315T>G p.F105L | Missense Mutation (SNP) | VAF 96/393 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs1277209901, COSV58600109; called by muse, mutect2, varscan2
- KIAA0319 | c.2666T>C p.L889P | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65499717; called by muse, mutect2, varscan2
- KIAA1217 | c.2656C>A p.H886N | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV100286145, COSV56812543; called by muse, mutect2
- KIF3B | c.1579T>C p.Y527H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs1299342544, COSV100996305; called by muse, mutect2
- KIFBP | c.566C>T p.P189L | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as COSV62831971; called by muse, mutect2, varscan2
- KIRREL1 | c.1750G>A p.D584N | Missense Mutation (SNP) | VAF 32/314 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.82); catalogued as rs778087275, COSV63288541; called by muse, mutect2
- KIRREL2 | c.2053G>C p.A685P | Missense Mutation (SNP) | VAF 23/195 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV52877584; called by muse, mutect2, varscan2
- KLC1 | c.937T>C p.Y313H | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV55808995; called by muse, mutect2, varscan2
- KLF15 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.019); catalogued as rs775981060, COSV56179851; called by muse, mutect2, varscan2
- KRBA2 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 62/229 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.132); catalogued as COSV58779264; called by muse, mutect2, varscan2
- KRT31 | c.178A>G p.M60V | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV52436205; called by muse, mutect2, varscan2
- KRTAP12-1 | c.58T>C p.C20R | Missense Mutation (SNP) | VAF 48/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100551719; called by muse, varscan2
- LAMA4 | c.5440G>A p.A1814T (on ENST00000230538 / NM_001105206.3; = p.A1807T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1048588170, COSV57899879; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMP3 | c.584C>T p.T195M | Missense Mutation (SNP) | VAF 49/431 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs570150710, COSV55615534; called by muse, mutect2, varscan2
- LANCL2 | c.739C>T p.R247C | Missense Mutation (SNP) | VAF 46/312 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs776342559, COSV54650108; called by muse, mutect2, varscan2
- LDHA | c.361A>G p.I121V | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs746460566, COSV99908004; called by muse, mutect2
- LENG8 | c.2146C>T p.R716W | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as rs757513843, COSV58728741; called by muse, mutect2, varscan2
- LEPR | c.1525T>C p.Y509H | Missense Mutation (SNP) | VAF 11/194 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100756244; called by muse, mutect2
- LETMD1 | c.176A>G p.Y59C | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as COSV50398160; called by muse, mutect2, varscan2
- LHX6 | c.702G>A p.M234I (on ENST00000373755 / NM_001242334.2; = p.M263I on NM_014368.5) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV61345062; called by muse, mutect2, varscan2
- LIG4 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100799676; called by muse, mutect2
- LIM2 | c.503G>A p.R168H (on ENST00000596399 / NM_001161748.2; = p.R210H on NM_030657.4) | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as rs375797744; called by muse, mutect2, varscan2
- LIMA1 | c.1940A>G p.N647S | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57966481; called by muse, mutect2, varscan2
- LIMS2 | c.503A>G p.H168R (on ENST00000355119 / NM_001161403.3; = p.H192R on NM_017980.4) | Missense Mutation (SNP) | VAF 30/208 reads (14%) | SIFT tolerated (0.63); PolyPhen benign (0.062); catalogued as COSV55755903; called by muse, mutect2, varscan2
- LMO3 | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as COSV53783436; called by muse, mutect2, varscan2
- LRIG1 | c.704A>T p.N235I | Missense Mutation (SNP) | VAF 58/369 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as COSV56242713; called by muse, varscan2
- LRIG2 | c.1706A>G p.N569S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV63164715; called by muse, mutect2
- LRPAP1 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 58/174 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs374011051; called by muse, mutect2, varscan2
- LRRC32 | c.442G>A p.A148T | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.327); catalogued as rs757982373, COSV52633810; called by muse, mutect2, varscan2
- LRRC73 | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.075); catalogued as rs769558368, COSV52499627; called by muse, mutect2, varscan2
- LRRC8A | c.1346A>G p.E449G | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as COSV52187044; called by muse, mutect2
- LRRC8A | c.1784A>C p.E595A | Missense Mutation (SNP) | VAF 31/351 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.195); catalogued as COSV99396218; called by muse, mutect2
- LRRK1 | c.2300G>A p.R767H | Missense Mutation (SNP) | VAF 17/154 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs753053998, COSV52617087; called by muse, mutect2, varscan2
- LRRN2 | c.1565G>C p.G522A | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV65784170; called by muse, mutect2, varscan2
- LTBP4 | c.3190G>A p.V1064M (on ENST00000308370 / NM_001042544.1; = p.V1027M on NM_003573.2) | Missense Mutation (SNP) | VAF 24/318 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs748078658, COSV99180351; ClinVar: likely benign; called by muse, mutect2
- MACF1 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 8/147 reads (5%) | catalogued as COSV57102933, COSV57103434; called by muse, mutect2
- MAD1L1 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 27/222 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs765227766, COSV56238882; called by muse, mutect2, varscan2
- MAG | c.973G>A p.A325T | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); catalogued as COSV62700426, COSV62701369; called by muse, mutect2, varscan2
- MAGEB18 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1297948059, COSV99082041; called by muse, mutect2
- MAGEC3 | c.1243C>A p.P415T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.022); catalogued as COSV68923869; called by muse, mutect2, varscan2
- MAGEE1 | c.1217C>A p.P406H | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.407); catalogued as COSV100819378, COSV63910791; called by muse, mutect2, varscan2
- MALSU1 | c.120G>T p.Q40H | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as COSV99799801; called by muse, mutect2
- MAMDC4 | c.3119G>A p.R1040H (on ENST00000445819; = p.R961H on NM_206920.3) | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.912); catalogued as rs1163142013, COSV56376361; called by muse, mutect2, varscan2
- MAN2B2 | c.2731C>T p.R911C | Missense Mutation (SNP) | VAF 16/137 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs200356754, COSV53454525; called by mutect2, varscan2
- MAP2K7 | c.1145G>A p.R382H | Missense Mutation (SNP) | VAF 23/235 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs759229847, COSV101208964, COSV101208984; called by muse, mutect2, varscan2
- MAP3K19 | c.2543C>T p.P848L | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV59640269; called by muse, mutect2, varscan2
- MAPK7 | c.671C>T p.T224M | Missense Mutation (SNP) | VAF 42/253 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55190548; called by muse, mutect2, varscan2
- MAPKAPK2 | c.769C>T p.L257= | Splice Region (SNP) | VAF 28/285 reads (10%) | catalogued as COSV99685703, COSV99685900; called by muse, mutect2
- MARS1 | c.383T>C p.L128S | Missense Mutation (SNP) | VAF 65/541 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1236377068, COSV56256463; called by muse, mutect2, varscan2
- MATK | c.1405C>T p.P469S (on ENST00000310132 / NM_139355.3; = p.P470S on NM_002378.4) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59555425; called by muse, mutect2, varscan2
- MBD6 | c.560del p.P187Qfs*81 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs1565663579, COSV63074771; called by mutect2, varscan2
- MCM6 | c.2011G>C p.E671Q | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV51467444; called by muse, mutect2, varscan2
- MCOLN1 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 123/512 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs746356009, COSV51177099; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 31/114 reads (27%) | catalogued as rs773080349; called by mutect2, pindel, varscan2
- MED12L | c.6115C>A p.L2039I | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.424); catalogued as COSV56384779; called by muse, mutect2, varscan2
- MED13 | c.301+2T>C p.X101_splice | Splice Site (SNP) | VAF 18/150 reads (12%) | catalogued as COSV101180733; called by muse, mutect2, varscan2
- MELTF | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1278271274, COSV56382655; called by muse, mutect2, varscan2
- MEPCE | c.1313A>C p.K438T | Missense Mutation (SNP) | VAF 21/387 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.11); catalogued as COSV99439766; called by muse, mutect2
- MERTK | c.2550G>C p.L850F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54931620, COSV54932366; called by muse, mutect2, varscan2
- MIOS | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as COSV60768543, COSV60771125; called by muse, mutect2
- MLKL | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV58205661; called by muse, mutect2, varscan2
- MMP15 | c.172C>T p.R58W | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs201766277; called by muse, mutect2, varscan2
- MMRN2 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1564736417, COSV62318029; called by muse, mutect2
- MOCS3 | c.614C>A p.A205D | Missense Mutation (SNP) | VAF 36/168 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54866840; called by muse, mutect2, varscan2
- MPG | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 16/172 reads (9%) | catalogued as rs199655862; called by muse, mutect2
- MRI1 | c.988del p.H330Tfs*24 (on ENST00000040663 / NM_001031727.4; = p.H283Tfs*24 on NM_032285.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 35/265 reads (13%) | catalogued as rs751646149; called by mutect2, pindel, varscan2
- MTHFR | c.1267G>A p.E423K | Missense Mutation (SNP) | VAF 22/167 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs757268352, COSV57173143; called by muse, mutect2, varscan2
- MTMR4 | c.1546T>C p.C516R | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs745483455, COSV60201451; called by mutect2, varscan2
- MUC16 | c.36518T>C p.I12173T | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.351); catalogued as COSV67476190; called by muse, mutect2, varscan2
- MUC4 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.494); catalogued as COSV62161778; called by muse, mutect2, varscan2
- MUC5B | c.5357C>T p.P1786L | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs371254219; called by muse, mutect2, varscan2
- MUSK | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.387); catalogued as rs758427621, COSV51889574; called by muse, varscan2
- MYH14 | c.1439C>T p.A480V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765142655, COSV51822697; called by mutect2, varscan2
- MYH6 | c.5335G>A p.A1779T | Missense Mutation (SNP) | VAF 166/425 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.869); catalogued as rs777220078, COSV59306546; called by muse, mutect2, varscan2
- MYH6 | c.4900G>A p.A1634T | Missense Mutation (SNP) | VAF 307/778 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); catalogued as rs369767936; called by muse, mutect2, varscan2
- MYO18B | c.3512T>C p.V1171A | Missense Mutation (SNP) | VAF 50/198 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV59139150; called by muse, varscan2
- MYO1E | c.1343A>G p.D448G | Missense Mutation (SNP) | VAF 27/221 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55690082; called by muse, mutect2, varscan2
- MYOC | c.204G>A p.M68I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV99231285; called by muse, mutect2
- NCDN | c.1532C>A p.P511H | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.515); catalogued as COSV100621879; called by muse, mutect2
- NCKAP5 | c.139T>C p.W47R | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); catalogued as COSV58454820; called by muse, mutect2, varscan2
- NCOR1 | c.4882C>T p.R1628C | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754505756, COSV51981965; called by muse, mutect2, varscan2
- NEDD1 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57144434; called by muse, mutect2, varscan2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 74/697 reads (11%) | catalogued as rs752284115; called by mutect2, varscan2
- NFE2 | c.1055T>C p.L352P | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56456317; called by muse, mutect2, varscan2
- NFKB2 | c.419A>G p.H140R | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51872736; called by muse, mutect2, varscan2
- NIPBL | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV56952557; called by muse, mutect2, varscan2
- NISCH | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.932); catalogued as rs773401264, COSV61900888; called by muse, mutect2, varscan2
- NISCH | c.3322A>C p.S1108R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV61900896; called by muse, mutect2, varscan2
- NPBWR1 | c.283G>A p.A95T | Missense Mutation (SNP) | VAF 49/269 reads (18%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.976); catalogued as COSV58696760; called by muse, mutect2, varscan2
- NPHP4 | c.1049G>A p.G350D | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.014); catalogued as COSV65395864; called by muse, mutect2, varscan2
- NRAS | c.170A>C p.D57A | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV54751243; called by muse, mutect2, varscan2
- NRSN2 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs780211474, COSV66526820; called by muse, mutect2, varscan2
- NRXN2 | c.3908G>A p.G1303D | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.752); catalogued as rs772463642, COSV55448437; called by muse, mutect2
- NT5C1A | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 57/348 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV52495200; called by muse, mutect2, varscan2
- NUAK2 | c.603T>G p.H201Q | Missense Mutation (SNP) | VAF 29/275 reads (11%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV65681832; called by muse, mutect2, varscan2
- NUDT14 | c.214C>T p.R72C | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs776403747, COSV59650356; called by muse, mutect2, varscan2
- NXF1 | c.986A>C p.D329A | Missense Mutation (SNP) | VAF 83/270 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV53674735; called by muse, mutect2, varscan2
- OBSCN | c.9994C>A p.R3332S | Missense Mutation (SNP) | VAF 143/1445 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.149); catalogued as COSV99471867; called by muse, mutect2
- ODF3L1 | c.676G>A p.A226T | Missense Mutation (SNP) | VAF 37/169 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs147726214; called by muse, mutect2, varscan2
- OGA | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as COSV100761645; called by muse, mutect2
- OR10H4 | c.632G>A p.G211D | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV59062256; called by muse, mutect2, varscan2
- OR1E1 | c.254T>C p.M85T | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV100491869; called by muse, mutect2
- OR2F2 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 45/273 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as COSV68832973; called by muse, mutect2, varscan2
- OR5J2 | c.736A>G p.T246A | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); catalogued as COSV100398884; called by muse, mutect2, varscan2
- OR9G4 | c.310del p.S104Pfs*4 | Frame Shift Del (DEL) | VAF 6/30 reads (20%) | catalogued as rs760558507; called by mutect2, pindel, varscan2
- OVOL2 | c.749T>C p.L250P | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV53860990; called by muse, mutect2, varscan2
- PABPC3 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 104/701 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs760196305, COSV55796443; called by muse, varscan2
- PAF1 | c.1067T>C p.M356T | Missense Mutation (SNP) | VAF 95/479 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.647); catalogued as COSV55392505; called by muse, mutect2, varscan2
- PAK2 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV100505812; called by muse, mutect2, varscan2
- PARP11 | c.479C>T p.T160M | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV57395509; called by muse, mutect2, varscan2
- PCDH19 | c.2710C>A p.L904M (on ENST00000373034 / NM_001184880.2; = p.L856M on NM_020766.3) | Missense Mutation (SNP) | VAF 46/205 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV55266012; called by muse, mutect2, varscan2
- PCDHA10 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as rs782304851, COSV56492965; called by muse, mutect2, varscan2
- PCDHA10 | c.1001C>T p.T334M | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.4); catalogued as rs1390810771, COSV56518645; called by muse, mutect2, varscan2
- PCDHGA5 | c.1855G>A p.V619I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.311); catalogued as COSV53976220; called by muse, mutect2, varscan2
- PCDHGC4 | c.659C>T p.P220L | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV52757142; called by muse, mutect2, varscan2
- PCNT | c.4516C>T p.L1506F | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64029992; called by muse, mutect2, varscan2
- PCNX3 | c.3385G>A p.A1129T | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1286267409, COSV63138227; called by muse, mutect2, varscan2
- PCYOX1 | c.1168A>T p.R390* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as COSV52476992; called by mutect2, varscan2
- PDZD4 | c.2065C>T p.R689C | Missense Mutation (SNP) | VAF 54/167 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99381026; called by muse, mutect2, varscan2
- PDZD7 | c.814A>G p.S272G | Missense Mutation (SNP) | VAF 60/547 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.976); catalogued as COSV64646742; called by muse, mutect2, varscan2
- PDZRN3 | c.1997A>G p.Y666C | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV99727107; called by muse, mutect2
- PER2 | c.1102G>A p.V368M | Missense Mutation (SNP) | VAF 35/244 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.233); catalogued as rs199558711, COSV54524977; called by muse, mutect2, varscan2
- PER3 | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100728195; called by muse, varscan2
- PFDN2 | c.11A>G p.N4S | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV100919023; called by muse, mutect2, varscan2
- PGAP2 | c.686C>T p.A229V (on ENST00000463452 / NM_001346398.2; = p.A290V on NM_014489.4) | Missense Mutation (SNP) | VAF 80/332 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs753497329, COSV53465426; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PGF | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV53126016; called by muse, mutect2, varscan2
- PHF2 | c.73G>A p.A25T | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as COSV63681813; called by muse, mutect2, varscan2
- PIGQ | c.1468C>A p.L490I | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.076); catalogued as COSV50315988; called by muse, mutect2, varscan2
- PIGT | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 38/269 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54127160; called by muse, mutect2, varscan2
- PIGV | c.1169T>C p.L390P | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99314724; called by muse, mutect2
- PITPNB | c.300T>C p.N100= | Splice Region (SNP) | VAF 16/56 reads (29%) | catalogued as COSV58061857; called by muse, mutect2, varscan2
- PKD1L1 | c.2098A>G p.T700A | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56969787; called by muse, mutect2, varscan2
- PLAT | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.051); catalogued as rs760967419, COSV54276509; called by muse, mutect2, varscan2
- PLB1 | c.2442C>A p.F814L | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV59829159; called by muse, mutect2, varscan2
- PLEC | c.8752T>C p.Y2918H (on ENST00000322810 / NM_201380.4; = p.Y2808H on NM_000445.5) | Missense Mutation (SNP) | VAF 29/194 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as COSV100509971; called by muse, mutect2, varscan2
- PLEC | c.1014G>A p.K338= (on ENST00000322810 / NM_201380.4; = p.K228= on NM_000445.5) | Splice Region (SNP) | VAF 42/494 reads (9%) | catalogued as COSV100509975; called by muse, mutect2
- PLEKHA5 | c.3187G>A p.E1063K | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as rs376373462, COSV54694670; called by muse, mutect2, varscan2
- PLLP | c.432+2T>C p.X144_splice | Splice Site (SNP) | VAF 12/107 reads (11%) | catalogued as COSV99535937; called by muse, mutect2
- PLPPR2 | c.506T>C p.L169P | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as COSV99264185; called by muse, mutect2, varscan2
- PLXNA2 | c.4633C>T p.R1545W | Missense Mutation (SNP) | VAF 47/358 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756497678, COSV65437667; called by muse, mutect2, varscan2
- POLR1A | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 79/602 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.961); catalogued as rs373061040; called by muse, mutect2, varscan2
- POLR1B | c.2768G>A p.R923H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54500143; called by muse, mutect2, varscan2
- POMGNT1 | c.1650-2A>C p.X550_splice | Splice Site (SNP) | VAF 19/83 reads (23%) | catalogued as COSV64340179; called by muse, mutect2, varscan2
- POPDC2 | c.852G>T p.K284N | Missense Mutation (SNP) | VAF 33/284 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.302); catalogued as COSV51741920; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.2219_2223del p.L740Hfs*42 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs759936789; called by pindel, varscan2
- PPFIBP1 | c.2326A>G p.I776V (on ENST00000318304 / NM_177444.3; = p.I770V on NM_003622.4) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57294359; called by muse, mutect2, varscan2
- PPME1 | c.143A>G p.Q48R | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV60296976; called by muse, mutect2, varscan2
- PPP1R13L | c.2044G>A p.A682T | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV62908917; called by muse, mutect2, varscan2
- PPP1R9B | c.1697C>T p.A566V | Missense Mutation (SNP) | VAF 55/182 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV57541754; called by muse, mutect2, varscan2
- PPP2R3C | c.1136T>C p.I379T | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as COSV99805655; called by muse, mutect2, varscan2
- PPP3CA | c.1265C>T p.T422M | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.075); catalogued as rs745416220, COSV59926301; called by muse, mutect2, varscan2
- PRDM15 | c.3410A>G p.N1137S | Missense Mutation (SNP) | VAF 37/358 reads (10%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as rs762085177, COSV54155244; called by muse, mutect2
- PRKAR2A | c.1019C>T p.A340V | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1334259503, COSV55552743; called by muse, mutect2, varscan2
- PRKCB | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.477); catalogued as rs747105951, COSV57776596, COSV57783158; called by muse, mutect2
- PRMT8 | c.595A>G p.T199A | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as COSV99713108; called by muse, mutect2
- PRPF40B | c.2233C>T p.P745S (on ENST00000380281; = p.P732S on NM_012272.3) | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.03); catalogued as COSV53304037; called by muse, mutect2, varscan2
- PRRC2C | c.6954A>G p.S2318= (on ENST00000367742; = p.S2316= on NM_015172.4) | Splice Region (SNP) | VAF 14/103 reads (14%) | catalogued as rs534777054, COSV58907794; called by muse, mutect2, varscan2
- PRSS3 | c.255G>T p.K85N (on ENST00000361005 / NM_007343.4; = p.K193N on NM_002771.3) | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100725034; called by muse, mutect2, varscan2
- PRX | c.2874G>T p.K958N | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV52532835, COSV99397394; called by muse, mutect2
- PTDSS2 | c.286G>T p.G96C | Missense Mutation (SNP) | VAF 89/622 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57278809, COSV57278821; called by muse, mutect2, varscan2
- PTGES3L-AARSD1 | c.911T>C p.L304P (on ENST00000421990 / NM_001136042.2; = p.L286P on NM_025267.3) | Missense Mutation (SNP) | VAF 30/315 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs1202205949, COSV100799182; called by muse, mutect2, varscan2
- PTGFRN | c.1744C>T p.R582C | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs1410831066, COSV67798915; called by mutect2, varscan2
- PTPN21 | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs141951135; called by muse, mutect2, varscan2
- PTPN23 | c.3709C>T p.R1237C | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.877); catalogued as rs755103681, COSV55543591; called by muse, mutect2, varscan2
- PTPN7 | c.329G>A p.S110N (on ENST00000495688; = p.S149N on NM_002832.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/545 reads (8%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100459603; called by muse, mutect2
- PTPRC | c.1538G>A p.G513D | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100722081; called by muse, mutect2
- PTPRU | c.3862T>C p.C1288R | Missense Mutation (SNP) | VAF 20/183 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1490905370, COSV60530635; called by muse, mutect2, varscan2
- RAB3D | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 48/367 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs144435530; called by muse, mutect2, varscan2
- RAI2 | c.386A>C p.H129P | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV58965093; called by muse, mutect2, varscan2
- RALBP1 | c.1316T>C p.L439P | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50034771; called by muse, mutect2, varscan2
- RALGAPA2 | c.4543G>A p.E1515K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV52501930; called by muse, mutect2, varscan2
- RBM10 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 72/495 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.034); catalogued as rs782408699, COSV100238105, COSV61310033; called by muse, mutect2, varscan2
- RBM27 | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV54591440; called by muse, mutect2, varscan2
- RCC1 | c.298G>T p.G100* | Nonsense Mutation (SNP) | VAF 56/353 reads (16%) | catalogued as COSV65779677; called by muse, mutect2, varscan2
- REC8 | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs561304496, COSV61017139; called by muse, mutect2, varscan2
- RETREG3 | c.581A>G p.Y194C | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1339227537, COSV58704479; called by muse, mutect2, varscan2
- RFLNB | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.018); catalogued as rs782206933, COSV61239599; called by muse, mutect2, varscan2
- RFX1 | c.2282C>T p.A761V | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as rs1483602267, COSV54330973; called by muse, mutect2, varscan2
- RGS11 | c.767G>A p.G256D (on ENST00000397770 / NM_183337.3; = p.G235D on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs564581589, COSV51453106; called by muse, mutect2, varscan2
- RMDN3 | c.487T>G p.S163A | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.203); catalogued as COSV53024562; called by muse, mutect2
- RNF112 | c.115A>C p.K39Q | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV71978890; called by muse, mutect2, varscan2
- RNF19A | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs767726348, COSV61993824; called by muse, varscan2
- RP1 | c.2570C>A p.S857* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | catalogued as COSV55120037; called by muse, mutect2
- RPGR | c.1397T>C p.M466T | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100139544; called by muse, mutect2
- RPL31 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.012); catalogued as COSV51822191; called by muse, mutect2, varscan2
- RPTOR | c.1088C>T p.T363I | Missense Mutation (SNP) | VAF 42/230 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV60811509; called by muse, mutect2, varscan2
- RRNAD1 | c.530T>C p.L177S | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207689289, COSV57460639; called by muse, mutect2, varscan2
- RTL9 | c.3010T>G p.S1004A | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV71825837; called by muse, mutect2, varscan2
- RTN4 | c.3359A>C p.K1120T (on ENST00000337526 / NM_020532.5; = p.K127T on NM_007008.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766328522, COSV58269609; called by muse, mutect2
- SACS | c.4099T>C p.Y1367H | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV66542579; called by muse, mutect2, varscan2
- SALL2 | c.247C>G p.P83A | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV58104203; called by muse, mutect2, varscan2
- SCAI | c.832G>A p.A278T (on ENST00000336505 / NM_001144877.3; = p.A301T on NM_173690.5) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.688); catalogued as rs369558159; called by muse, mutect2, varscan2
- SCARF1 | c.1889G>A p.R630Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs528173063, COSV99556811; called by muse, mutect2
- SCNN1D | c.635G>A p.S212N (on ENST00000338555; = p.S376N on NM_001130413.4) | Missense Mutation (SNP) | VAF 13/102 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV57641456; called by muse, mutect2, varscan2
- SCNN1G | c.1891C>T p.R631C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs150854967; called by muse, mutect2, varscan2
- SCYL1 | c.379G>T p.A127S | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV54213644; called by muse, mutect2, varscan2
- SDF4 | c.470T>C p.V157A | Missense Mutation (SNP) | VAF 84/612 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV55420166; called by muse, mutect2, varscan2
- SDK1 | c.2213C>T p.T738I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV67376405; called by muse, mutect2, varscan2
- SEC16A | c.6390G>A p.S2130= | Splice Region (SNP) | VAF 35/356 reads (10%) | catalogued as rs1255161099, COSV51533640; called by muse, mutect2, varscan2
- SEL1L2 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.69); catalogued as COSV53154205; called by muse, mutect2, varscan2
- SELENOF | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs375315291; called by muse, mutect2, varscan2
- SELP | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738888; called by muse, mutect2, varscan2
- SEMA4C | c.1555T>C p.W519R | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100560712; called by muse, mutect2, varscan2
- SEMA4D | c.621C>T p.N207= | Splice Region (SNP) | VAF 37/131 reads (28%) | catalogued as rs371952126; called by muse, mutect2, varscan2
- SEMA4F | c.1268G>A p.G423D | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.18); PolyPhen benign (0.141); catalogued as COSV60282066; called by muse, mutect2, varscan2
- SEPTIN5 | c.233C>A p.A78D | Missense Mutation (SNP) | VAF 16/154 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV63530783; called by muse, mutect2, varscan2
- SERINC3 | c.1060C>T p.R354C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs758967791, COSV54857452; called by muse, mutect2
- SETD7 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as COSV56800224; called by muse, mutect2, varscan2
- SETDB1 | c.201G>T p.W67C | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.667); catalogued as COSV99643652; called by muse, mutect2
- SGIP1 | c.2425G>T p.G809W | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52772581; called by muse, mutect2, varscan2
- SH2B2 | c.1438C>G p.R480G | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.871); catalogued as COSV100159650, COSV60826661; called by muse, mutect2, varscan2
- SH2D2A | c.1134A>C p.R378S | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV63885009; called by muse, mutect2, varscan2
- SH3KBP1 | c.262A>C p.T88P | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV65642659; called by muse, mutect2, varscan2
- SH3PXD2A | c.1174G>A p.V392M (on ENST00000369774 / NM_001365079.1; = p.V364M on NM_014631.2) | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs553552960, COSV60118273; called by muse, mutect2, varscan2
- SH3RF1 | c.1762A>G p.N588D | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.112); catalogued as rs1361003609, COSV52922304; called by muse, mutect2, varscan2
- SHANK1 | c.1137C>G p.N379K | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV53254505; called by muse, mutect2, varscan2
- SLC12A3 | c.55C>T p.R19C | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs374055486; called by muse, mutect2, varscan2
- SLC14A1 | c.718T>C p.W240R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as rs760579000, COSV58932929; called by mutect2, varscan2
- SLC1A6 | c.250C>A p.R84S | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV55671582; called by muse, mutect2, varscan2
- SLC25A10 | c.472A>G p.R158G | Missense Mutation (SNP) | VAF 20/397 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV100518908; called by muse, mutect2
- SLC25A31 | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 48/206 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs779889234, COSV55418886; called by muse, mutect2, varscan2
- SLC25A40 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 28/233 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs1025869757, COSV62020598; called by muse, mutect2, varscan2
- SLC25A47 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59926184; called by muse, mutect2, varscan2
- SLC2A6 | c.1385A>C p.Q462P | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.338); catalogued as COSV52470707, COSV99390339; called by muse, mutect2, varscan2
- SLC30A1 | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.023); catalogued as COSV100879092; called by muse, mutect2
- SLC30A7 | c.389C>T p.A130V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.511); catalogued as COSV63017985; called by muse, mutect2
- SLC35B1 | c.766+2T>C p.X256_splice (on ENST00000649906; = p.X219_splice on NM_005827.4) | Splice Site (SNP) | VAF 44/326 reads (13%) | catalogued as COSV99539347; called by muse, mutect2, varscan2
- SLC50A1 | c.415A>C p.S139R | Missense Mutation (SNP) | VAF 17/263 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.532); catalogued as COSV100310204; called by muse, mutect2
- SLC52A1 | c.1292G>A p.S431N | Missense Mutation (SNP) | VAF 25/206 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs1313841143, COSV54693214; called by muse, mutect2, varscan2
- SLC66A1 | c.53C>A p.S18Y | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV64321078; called by muse, mutect2, varscan2
- SLC6A20 | c.673A>G p.M225V | Missense Mutation (SNP) | VAF 26/266 reads (10%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV100653538; called by muse, mutect2, varscan2
- SLC6A3 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1460025546, COSV54365777; called by muse, mutect2, varscan2
- SLC6A6 | c.1045G>A p.G349S | Missense Mutation (SNP) | VAF 55/528 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62650685; called by muse, mutect2, varscan2
- SLC6A8 | c.393A>T p.K131N | Missense Mutation (SNP) | VAF 39/259 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as COSV53472632; called by muse, mutect2, varscan2
- SLC7A9 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753115478, COSV50083388; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLCO2A1 | c.574A>G p.I192V | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60486956; called by muse, mutect2
- SLCO5A1 | c.299A>G p.D100G | Missense Mutation (SNP) | VAF 14/269 reads (5%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV99479308; called by muse, mutect2
- SLFN13 | c.833C>G p.S278C | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV53194212; called by muse, mutect2, varscan2
- SLITRK1 | c.1385T>C p.I462T | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100999764; called by muse, mutect2
- SMARCA4 | c.2900G>A p.R967H | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1085307769, COSV60799938; called by muse, mutect2, varscan2
- SMARCB1 | c.646G>A p.V216I (on ENST00000263121; = p.V262I on NM_003073.5) | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.85); catalogued as rs1341827515, COSV54093872; called by muse, mutect2, varscan2
- SMARCC1 | c.2023G>A p.D675N | Missense Mutation (SNP) | VAF 28/93 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.054); catalogued as COSV54382904; called by muse, mutect2, varscan2
- SMARCE1 | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs761299232, COSV52861288; called by muse, mutect2, varscan2
- SMCR8 | c.2423G>A p.S808N | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1567760672, COSV68811131; called by muse, mutect2, varscan2
- SMG9 | c.1400A>G p.Q467R | Missense Mutation (SNP) | VAF 18/163 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.011); catalogued as COSV54215234; called by muse, mutect2, varscan2
- SNTB1 | c.1199C>T p.T400M | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); catalogued as rs199549031, COSV67327410; called by muse, mutect2, varscan2
- SOCS6 | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.041); catalogued as rs762157657, COSV67546137; called by muse, mutect2, varscan2
- SOX13 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs772429096, COSV65827026; called by muse, mutect2, varscan2
- SP100 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50986487; called by muse, mutect2, varscan2
- SP4 | c.1337T>G p.L446R | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.655); catalogued as COSV99753968; called by muse, mutect2
- SPATA2 | c.1414T>C p.C472R | Missense Mutation (SNP) | VAF 89/459 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1568905618, COSV56867239; called by muse, mutect2, varscan2
- SPNS2 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs759366061, COSV61230904; called by muse, mutect2, varscan2
- SPSB1 | c.207G>T p.E69D | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV60163778; called by muse, mutect2, varscan2
- SPTBN1 | c.3749T>G p.V1250G | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.315); catalogued as COSV61690135; called by muse, mutect2, varscan2
- SRCAP | c.7249G>A p.A2417T | Missense Mutation (SNP) | VAF 26/180 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs773086154, COSV52670594; called by muse, mutect2, varscan2
- SRGAP2 | c.1956G>T p.E652D (on ENST00000624873 / NM_001170637.4; = p.E653D on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.029); catalogued as COSV99832335; called by muse, mutect2
- SRPX2 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.037); catalogued as COSV65933931; called by muse, mutect2, varscan2
- SSBP2 | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.374); catalogued as COSV100282995; called by muse, mutect2
- SSRP1 | c.1045T>C p.S349P | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.173); catalogued as COSV53480224; called by muse, mutect2, varscan2
- STAB1 | c.2006G>A p.C669Y | Missense Mutation (SNP) | VAF 29/263 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58739103; called by muse, mutect2, varscan2
- STARD7 | c.484C>A p.L162I | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.456); catalogued as COSV61526194; called by muse, mutect2, varscan2
- STARD8 | c.943G>A p.V315M | Missense Mutation (SNP) | VAF 55/212 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.222); catalogued as rs151192738, COSV99366127; called by muse, mutect2, varscan2
- STRN4 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs769814736, COSV99623250; called by muse, mutect2, varscan2
- SUGP1 | c.1716G>C p.K572N | Missense Mutation (SNP) | VAF 50/519 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99894479; called by muse, mutect2
- SULF2 | c.1492G>A p.G498R | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs149787530; called by muse, mutect2, varscan2
- SUN3 | c.955-2A>G p.X319_splice | Splice Site (SNP) | VAF 6/62 reads (10%) | catalogued as COSV99813790; called by muse, mutect2
- SUN5 | c.820C>A p.L274I | Missense Mutation (SNP) | VAF 81/623 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as COSV62181596; called by muse, mutect2, varscan2
- SURF4 | c.478G>T p.G160* | Nonsense Mutation (SNP) | VAF 45/134 reads (34%) | catalogued as COSV64332457; called by muse, mutect2, varscan2
- SYNPO2L | c.874T>C p.S292P (on ENST00000394810 / NM_001114133.3; = p.S68P on NM_024875.5) | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65737777; called by muse, mutect2, varscan2
- SYTL4 | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV52169067; called by muse, mutect2, varscan2
- TAB2 | c.928A>G p.S310G | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV53853430; called by muse, mutect2, varscan2
- TACC2 | c.8277A>G p.I2759M (on ENST00000334433; = p.I837M on NM_006997.4) | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV53283824; called by muse, mutect2, varscan2
- TAF1L | c.2495G>A p.R832H | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479130837, COSV54258209; called by muse, mutect2, varscan2
- TAF4 | c.1568T>C p.I523T | Missense Mutation (SNP) | VAF 56/234 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as rs1198278771, COSV53339330; called by muse, mutect2, varscan2
- TARBP2 | c.791C>A p.T264N (on ENST00000266987 / NM_134323.2; = p.T243N on NM_004178.4) | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99908368; called by muse, mutect2
- TAS1R1 | c.127C>A p.L43M | Missense Mutation (SNP) | VAF 35/289 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as COSV60229017; called by muse, mutect2, varscan2
- TBC1D2 | c.1868G>A p.R623Q | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761820400, COSV59785989; called by muse, mutect2, varscan2
- TBC1D2 | c.1691G>T p.G564V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59786064; called by muse, mutect2, varscan2
- TBC1D28 | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 125/527 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs201108698, COSV61507741; called by muse, mutect2, varscan2
- TBL2 | c.943_945del p.K315del | In Frame Del (DEL) | VAF 9/90 reads (10%) | catalogued as rs1554587348; called by pindel, varscan2
- TBL2 | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 72/631 reads (11%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.486); catalogued as COSV59787470; called by muse, mutect2, varscan2
- TBX3 | c.1949C>T p.P650L (on ENST00000257566 / NM_016569.4; = p.P630L on NM_005996.4) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1308949255, COSV57470876, COSV57473091; called by muse, mutect2, varscan2
- TCEA2 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 25/245 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568253300, COSV58658359; called by muse, mutect2, varscan2
- TENM3 | c.707A>G p.Q236R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.932); catalogued as COSV69312399; called by muse, mutect2, varscan2
- TENM3 | c.6605C>T p.T2202M | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.353); catalogued as rs146065963, COSV69310305; called by muse, mutect2, varscan2
- TESMIN | c.187G>A p.V63I | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54833542; called by muse, mutect2, varscan2
- TF | c.1565T>C p.L522P | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99395319; called by muse, mutect2, varscan2
- TFE3 | c.613A>G p.T205A | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.097); catalogued as COSV59947764; called by muse, mutect2, varscan2
- TFPI2 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs768678727, COSV55989943; called by muse, mutect2, varscan2
- TG | c.3669G>T p.E1223D | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs757193116, COSV55082617; called by muse, mutect2, varscan2
- TGFBR3 | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53027727; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2230C>A p.H744N | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.823); catalogued as COSV51513626; called by muse, mutect2, varscan2
- TGM1 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 91/348 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as COSV52863970; called by muse, mutect2, varscan2
- TGS1 | c.102-1G>T p.X34_splice | Splice Site (SNP) | VAF 11/79 reads (14%) | catalogued as COSV52701098; called by muse, mutect2, varscan2
- THBS4 | c.1559A>G p.Q520R | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as COSV63467946; called by muse, mutect2, varscan2
- TICAM1 | c.1435C>T p.R479* | Nonsense Mutation (SNP) | VAF 24/164 reads (15%) | catalogued as COSV50233970; called by muse, mutect2, varscan2
- TIMM9 | c.176T>C p.M59T | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.56); catalogued as COSV53621853; called by muse, mutect2, varscan2
- TKT | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 21/145 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV56244380; called by muse, mutect2, varscan2
- TLN1 | c.4853G>A p.R1618Q | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as rs780560798, COSV59208994; called by muse, mutect2, varscan2
- TLR5 | c.2390A>G p.Q797R | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as COSV60559545; called by muse, mutect2, varscan2
- TM9SF2 | c.949A>G p.M317V | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.088); catalogued as COSV64507005; called by muse, mutect2, varscan2
- TMC3 | c.2756A>G p.E919G | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV63923618; called by muse, mutect2, varscan2
- TMEM190 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.033); catalogued as rs778558110, COSV52581992; called by muse, mutect2, varscan2
- TMEM59L | c.812C>A p.A271D | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99449935; called by muse, mutect2, varscan2
- TMPRSS7 | c.1997A>G p.Y666C (on ENST00000452346; = p.Y540C on NM_001042575.2) | Missense Mutation (SNP) | VAF 22/177 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.529); catalogued as COSV69981386; called by muse, mutect2, varscan2
- TMTC4 | c.1850A>G p.H617R (on ENST00000376234 / NM_001350577.2; = p.H636R on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 83/311 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs147952663; called by muse, mutect2, varscan2
- TNIP1 | c.350C>A p.P117Q | Missense Mutation (SNP) | VAF 31/370 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.576); catalogued as COSV100161086; called by muse, mutect2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNRC6B | c.5278G>T p.G1760* (on ENST00000454349 / NM_001162501.2; = p.G1650* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV57299980; called by muse, mutect2, varscan2
- TNXB | c.6919G>A p.G2307S (on ENST00000647633; = p.G2060S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.053); catalogued as rs1193752770, COSV64472638; called by muse, mutect2
- TNXB | c.5537T>A p.V1846D (on ENST00000647633; = p.V1599D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64482082; called by muse, mutect2, varscan2
- TOP3A | c.762G>T p.E254D | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as COSV58178745; called by muse, mutect2, varscan2
- TRAF2 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs762052203, COSV56039032; called by muse, mutect2, varscan2
- TRAK2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 13/92 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV60273156; called by muse, mutect2, varscan2
- TRAPPC8 | c.1917G>T p.Q639H | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51971165; called by muse, mutect2
- TRAPPC9 | c.2458C>A p.L820M | Missense Mutation (SNP) | VAF 29/155 reads (19%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.695); catalogued as COSV66903135; called by muse, mutect2, varscan2
- TRH | c.319del p.A107Lfs*23 | Frame Shift Del (DEL) | VAF 12/103 reads (12%) | catalogued as rs770451471, COSV57014685; called by mutect2, pindel, varscan2
- TRIM17 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs145425540; called by muse, mutect2, varscan2
- TRIM24 | c.1598C>A p.P533H (on ENST00000343526 / NM_015905.3; = p.P499H on NM_003852.4) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.459); catalogued as COSV58974099; called by mutect2, varscan2
- TRIM28 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 36/356 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs968993665, COSV99448634; called by muse, mutect2, varscan2
- TRIM46 | c.542A>G p.E181G | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55279407; called by muse, mutect2, varscan2
- TRIO | c.6457G>T p.G2153* | Nonsense Mutation (SNP) | VAF 29/268 reads (11%) | catalogued as COSV60086917; called by muse, mutect2, varscan2
- TRO | c.1831T>C p.S611P | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51503512; called by muse, mutect2, varscan2
- TRPC5 | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs768916869, COSV99459184; called by mutect2, varscan2
- TRPM2 | c.3136G>A p.A1046T | Missense Mutation (SNP) | VAF 69/347 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754688559, COSV55972041; called by muse, mutect2, varscan2
- TRPM3 | c.3881C>T p.T1294M (on ENST00000357533 / NM_001366142.2; = p.T1149M on NM_020952.6) | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as rs764791547, COSV62588898; called by muse, mutect2, varscan2
- TRPV3 | c.1868G>A p.G623D | Missense Mutation (SNP) | VAF 25/179 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.096); catalogued as rs1462294568, COSV100027370, COSV56792579; called by muse, mutect2, varscan2
- TSC22D4 | c.664G>A p.A222T | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.055); catalogued as rs371246798, COSV100278790; called by muse, mutect2
- TSHZ1 | c.2960G>C p.S987T (on ENST00000580243 / NM_001308210.2; = p.S942T on NM_005786.6) | Missense Mutation (SNP) | VAF 41/254 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.239); catalogued as COSV59012323; called by muse, mutect2, varscan2
- TSPAN1 | c.427A>G p.T143A | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100915340; called by muse, mutect2
- TSPOAP1 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 77/287 reads (27%) | catalogued as rs754987164, COSV52111775; called by muse, mutect2, varscan2
- TTC25 | c.76T>C p.C26R | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.023); catalogued as COSV66368536; called by muse, mutect2, varscan2
- TTC7B | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60634077; called by muse, mutect2, varscan2
- TUBA3E | c.1216C>T p.H406Y | Missense Mutation (SNP) | VAF 60/518 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.18); catalogued as COSV56059285; called by muse, mutect2, varscan2
- TUBAL3 | c.265C>A p.Q89K | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV100990447; called by muse, mutect2
- TUBGCP6 | c.1940T>C p.M647T | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50554696; called by muse, mutect2, varscan2
- TXNDC11 | c.1357A>G p.T453A (on ENST00000356957 / NM_001303447.2; = p.T426A on NM_015914.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as COSV51600503; called by muse, mutect2, varscan2
- TYK2 | c.3055T>C p.Y1019H | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV53388796; called by muse, mutect2, varscan2
- UBLCP1 | c.949G>T p.G317* | Nonsense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as COSV57143770, COSV57143850; called by muse, mutect2, varscan2
- UBXN11 | c.691G>A p.E231K (on ENST00000374221 / NM_183008.2; = p.E198K on NM_145345.2) | Missense Mutation (SNP) | VAF 23/181 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs916011692, COSV54625746; called by muse, mutect2, varscan2
- UCKL1 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.9); catalogued as rs1482322415, COSV62403201; called by muse, mutect2, varscan2
- ULK1 | c.644T>C p.L215P | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58857943; called by muse, mutect2, varscan2
- UNC13A | c.975G>T p.E325D | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as COSV53199925; called by muse, mutect2, varscan2
- UNC13B | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs770226679, COSV65935916; called by muse, mutect2, varscan2
- UNK | c.350A>C p.E117A | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV53143575, COSV99505403; called by muse, mutect2, varscan2
- UROC1 | c.1361C>T p.T454I | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99330807; called by muse, mutect2
- USP13 | c.2390C>A p.P797H | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55867246, COSV55870029; called by muse, mutect2, varscan2
- VCL | c.2339G>A p.R780H | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs1441017178, COSV53011266; called by muse, mutect2, varscan2
- VDR | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 52/368 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs371655308; called by muse, mutect2, varscan2
- VPS13D | c.5452G>A p.D1818N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV50650774; called by muse, mutect2, varscan2
- VPS9D1 | c.161T>C p.V54A | Missense Mutation (SNP) | VAF 32/229 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1567554871, COSV57069915; called by muse, mutect2, varscan2
- VWA2 | c.254C>A p.P85H | Missense Mutation (SNP) | VAF 27/148 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV53908007; called by muse, mutect2, varscan2
- WAPL | c.3133C>T p.R1045W | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs113314659, COSV53937186; called by muse, mutect2, varscan2
- WASF1 | c.766C>T p.P256S | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV63935761; called by muse, mutect2, varscan2
- WDR17 | c.3560A>G p.Y1187C | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54577246; called by muse, mutect2, varscan2
- WDR19 | c.3608G>T p.R1203M | Missense Mutation (SNP) | VAF 18/160 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56466950; called by muse, mutect2, varscan2
- WDR49 | c.620T>G p.L207R (on ENST00000308378 / NM_001366158.1; = p.L548R on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57705811, COSV57711347; called by muse, mutect2, varscan2
- WDR86 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 55/416 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as rs373857242; called by muse, mutect2, varscan2
- WDR88 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63451875; called by muse, mutect2, varscan2
- WDR92 | c.919G>A p.V307I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1233385271, COSV54562019; called by muse, mutect2, varscan2
- WNT2B | c.757C>T p.R253C (on ENST00000369684 / NM_024494.3; = p.R234C on NM_004185.4) | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as rs1408255377, COSV56675305; called by muse, mutect2, varscan2
- WWP2 | c.2431G>A p.E811K | Missense Mutation (SNP) | VAF 84/304 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766917559, COSV63122939; called by muse, mutect2, varscan2
- XPNPEP2 | c.124-1G>A p.X42_splice | Splice Site (SNP) | VAF 138/549 reads (25%) | catalogued as COSV64368014; called by muse, mutect2, varscan2
- YIF1B | c.559G>T p.G187W (on ENST00000339413 / NM_001039673.3; = p.G172W on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/110 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100007787; called by muse, mutect2
- YOD1 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 85/280 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV60005913, COSV60006565; called by muse, mutect2, varscan2
- ZBTB11 | c.1747G>A p.A583T | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.049); catalogued as rs76876070; called by muse, mutect2
- ZBTB37 | c.155C>T p.A52V | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100774501; called by muse, mutect2
- ZBTB40 | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs770580272, COSV65146927; called by muse, mutect2
- ZC3H12A | c.1792A>G p.S598G | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); catalogued as COSV100897634; called by muse, mutect2
- ZDHHC19 | c.687+2T>C p.X229_splice | Splice Site (SNP) | VAF 8/73 reads (11%) | catalogued as COSV99579328; called by muse, mutect2
- ZFP30 | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.987); catalogued as rs370737195, COSV63622476; called by muse, mutect2, varscan2
- ZGPAT | c.1310C>T p.A437V | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.036); catalogued as rs746868722, COSV56648941; called by muse, mutect2, varscan2
- ZIC4 | c.137T>G p.L46R | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101267807, COSV67172150; called by muse, mutect2
- ZMYM2 | c.1379A>G p.N460S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); catalogued as rs766102273, COSV67035428; called by mutect2, varscan2
- ZMYM4 | c.1595C>T p.A532V | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs765573029, COSV58911214; called by muse, mutect2, varscan2
- ZMYM6 | c.964C>A p.H322N | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as COSV64121497; called by muse, mutect2, varscan2
- ZNF112 | c.2047C>A p.H683N (on ENST00000337401 / NM_001083335.2; = p.H677N on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61620832; called by muse, mutect2, varscan2
- ZNF281 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 76/467 reads (16%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.749); catalogued as COSV54168277; called by muse, mutect2, varscan2
- ZNF319 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.827); catalogued as rs1356941680, COSV99539957; called by muse, mutect2, varscan2
- ZNF341 | c.281A>G p.Y94C | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs749369151, COSV61009651; called by muse, mutect2, varscan2
- ZNF41 | c.2338T>C p.*780Rext*16 | Nonstop Mutation (SNP) | VAF 13/63 reads (21%) | catalogued as rs753635329, COSV57443814; called by muse, mutect2, varscan2
- ZNF438 | c.215T>C p.L72P | Missense Mutation (SNP) | VAF 29/205 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59196703; called by muse, mutect2, varscan2
- ZNF536 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV62827405; called by muse, mutect2, varscan2
- ZNF546 | c.68A>G p.H23R | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as COSV100713338; called by muse, mutect2
- ZNF567 | c.1402C>G p.Q468E (on ENST00000536254 / NM_001322913.1; = p.Q437E on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV62445886; called by muse, mutect2, varscan2
- ZNF567 | c.1564C>G p.L522V (on ENST00000536254 / NM_001322913.1; = p.L491V on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.795); catalogued as COSV62445228; called by muse, mutect2, varscan2
- ZNF628 | c.2737G>A p.E913K | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.058); catalogued as rs1348721418, COSV52700539; called by muse, mutect2, varscan2
- ZNF687 | c.247A>G p.S83G | Missense Mutation (SNP) | VAF 8/115 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100133870; called by muse, mutect2
- ZNF697 | c.1156T>C p.C386R | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70284196; called by muse, mutect2, varscan2
- ZNF75A | c.357G>A p.M119I | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV73039618; called by muse, mutect2, varscan2
- ZNRF1 | c.377A>G p.D126G | Missense Mutation (SNP) | VAF 34/149 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.188); catalogued as COSV57728664; called by muse, mutect2, varscan2
- ZNRF4 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1235805061, COSV55774854; called by muse, mutect2, varscan2
- ZSCAN5A | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs368509037; called by muse, mutect2
- ZSCAN5A | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1300974044, COSV54228300; called by muse, mutect2
- ZSWIM4 | c.334G>A p.V112M | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs1336472794, COSV54323524; called by muse, mutect2
- ZYG11B | c.1555A>G p.S519G | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV53754275; called by muse, mutect2, varscan2
- ADGRV1 | c.10427_10429del p.X3476_splice | Splice Site (DEL) | VAF 7/51 reads (14%) | called by mutect2, pindel, varscan2
- AHNAK | c.12562del p.M4188Cfs*4 | Frame Shift Del (DEL) | VAF 20/132 reads (15%) | called by mutect2, varscan2
- ARHGEF12 | c.4279_4280del p.S1427Ffs*4 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by pindel, varscan2
- ARSG | c.185C>T p.A62V | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- ASF1A | c.477del p.K159Nfs*35 | Frame Shift Del (DEL) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- BBS2 | c.2160_2162del p.S721del | In Frame Del (DEL) | VAF 6/44 reads (14%) | called by pindel, varscan2
- CLCN2 | c.2134_2135del p.P713Hfs*22 | Frame Shift Del (DEL) | VAF 22/202 reads (11%) | called by pindel, varscan2
- DDB1 | c.685del p.A229Pfs*74 | Frame Shift Del (DEL) | VAF 13/92 reads (14%) | called by mutect2, pindel, varscan2
- FCGBP | c.7022G>A p.S2341N | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FCHSD2 | c.1568del p.K523Sfs*12 | Frame Shift Del (DEL) | VAF 17/129 reads (13%) | called by mutect2, pindel, varscan2
- GAB4 | c.153_174+7delinsGAGAAGAAGCTGAGGCTCTTTGTGAGTGC p.X51_splice | Splice Site (ONP) | VAF 6/55 reads (11%) | called by mutect2*, pindel, varscan2*
- GANAB | c.1378_1379del p.R460Afs*31 | Frame Shift Del (DEL) | VAF 30/135 reads (22%) | called by pindel, varscan2
- GLI3 | c.3098del p.P1033Rfs*46 | Frame Shift Del (DEL) | VAF 8/52 reads (15%) | called by mutect2, pindel
- ITGA4 | c.187dup p.A63Gfs*46 | Frame Shift Ins (INS) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- KCNQ4 | c.683G>A p.G228D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- KIAA1522 | c.1322del p.P441Lfs*13 (on ENST00000373480 / NM_001198972.2; = p.P500Lfs*13 on NM_020888.3) | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | called by mutect2, pindel
- MYCBP2 | c.7994A>G p.Q2665R (on ENST00000357337; = p.Q2703R on NM_015057.5) | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- MYH7B | c.4663+2T>C p.X1555_splice | Splice Site (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- NPVF | c.206del p.N69Mfs*5 | Frame Shift Del (DEL) | VAF 12/109 reads (11%) | called by mutect2, pindel
- NR1D1 | c.299del p.P100Lfs*26 | Frame Shift Del (DEL) | VAF 21/154 reads (14%) | called by mutect2, pindel, varscan2
- NR1I3 | c.728dup p.L243Ffs*20 (on ENST00000367982 / NM_001077480.3; = p.L239Ffs*20 on NM_005122.5) | Frame Shift Ins (INS) | VAF 13/78 reads (17%) | called by mutect2, pindel, varscan2
- NUP210 | c.1304T>C p.V435A | Missense Mutation (SNP) | VAF 16/238 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.248); called by muse, mutect2
- PCDHB10 | c.409_410del p.E137Nfs*11 | Frame Shift Del (DEL) | VAF 26/103 reads (25%) | called by mutect2, pindel, varscan2
- PCSK7 | c.1678del p.R560Afs*51 | Frame Shift Del (DEL) | VAF 19/118 reads (16%) | called by mutect2, varscan2
- POLR2A | c.3475T>C p.C1159R | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- PRAMEF14 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 27/333 reads (8%) | SIFT tolerated (0.96); PolyPhen benign (0.017); called by muse, mutect2
- PSIP1 | c.158del p.L53* | Frame Shift Del (DEL) | VAF 13/40 reads (33%) | called by mutect2, pindel, varscan2
- RETREG1 | c.656T>C p.L219P (on ENST00000306320 / NM_001034850.2; = p.L78P on NM_019000.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RNF169 | c.695C>A p.P232Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.543); called by muse, varscan2
- RTF1 | c.662G>T p.R221I | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- RYR2 | c.7246G>T p.A2416S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.947); called by muse, mutect2
- SAMD4A | c.871del p.L291Cfs*7 | Frame Shift Del (DEL) | VAF 9/59 reads (15%) | called by mutect2, pindel, varscan2
- SSUH2 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- TRAV4 | c.173G>A p.S58N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TXNDC5 | c.818del p.K273Rfs*14 | Frame Shift Del (DEL) | VAF 20/129 reads (16%) | called by mutect2, pindel, varscan2
- USP1 | c.660del p.E221Kfs*3 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | called by pindel, varscan2
- ZNF235 | c.951del p.K317Nfs*154 | Frame Shift Del (DEL) | VAF 5/27 reads (19%) | called by mutect2, pindel, varscan2
- ZNF572 | c.315dup p.P106Tfs*28 | Frame Shift Ins (INS) | VAF 13/123 reads (11%) | called by mutect2, pindel
- ZNF615 | c.1455_1456del p.I485Mfs*3 | Frame Shift Del (DEL) | VAF 26/160 reads (16%) | called by pindel, varscan2
- ZNF652 | c.1619del p.P540Lfs*43 | Frame Shift Del (DEL) | VAF 23/187 reads (12%) | called by mutect2, pindel, varscan2
- AACS | c.1839G>A p.A613= | Silent (SNP) | VAF 42/136 reads (31%) | catalogued as rs372980742; called by muse, mutect2, varscan2
- ABCA8 | c.4110G>A p.Q1370= | Silent (SNP) | VAF 11/107 reads (10%) | catalogued as COSV52201537; called by muse, mutect2, varscan2
- ABCG1 | c.1617G>A p.A539= | Silent (SNP) | VAF 34/243 reads (14%) | catalogued as rs762812239, COSV59206658; called by muse, mutect2, varscan2
- ACSBG1 | c.1170G>A p.A390= | Silent (SNP) | VAF 17/112 reads (15%) | catalogued as rs372203439; called by muse, mutect2, varscan2
288 further variants in this file (0 protein-altering or splice-affecting, 269 silent, 19 other) are not listed here.
